Somatic mutation profile of tumor specimen 0DVKDW from CCDI case PBCMDA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DVKDW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b6dd1c7-d33d-4e87-b8a9-4f8a5b6bf902.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVKED (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f13e00b7-01df-480a-9c40-65c9bb06cfd0

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 3, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCT8L2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.125); catalogued as rs772884061; called by muse, mutect2, varscan2
- HSPB7 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 235/254 reads (93%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.464); catalogued as rs561575565, COSV61307937; called by muse, mutect2, varscan2
- KRT20 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 274/622 reads (44%) | catalogued as rs574660500; called by muse, mutect2, varscan2
- MS4A6E | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 300/676 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs749700845, COSV55726292; called by muse, mutect2, varscan2
- NEB | c.7033G>T p.E2345* | Nonsense Mutation (SNP) | VAF 298/647 reads (46%) | catalogued as COSV99424156; called by muse, mutect2, varscan2
- SERPINB2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 199/420 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs527405738, COSV99449478; called by muse, mutect2, varscan2
- ADAM28 | c.818T>G p.L273W | Missense Mutation (SNP) | VAF 206/219 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf99 | c.193A>T p.T65S | Missense Mutation (SNP) | VAF 47/1046 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.12); called by muse, mutect2
- C2orf16 | c.3838A>T p.T1280S | Missense Mutation (SNP) | VAF 21/764 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2
- EIF4G3 | c.2186C>G p.A729G | Missense Mutation (SNP) | VAF 264/286 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- ELMO3 | c.1642G>A p.A548T (on ENST00000652269; = p.A495T on NM_024712.5) | Missense Mutation (SNP) | VAF 311/695 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LATS2 | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 146/261 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHLDB3 | c.1859C>G p.P620R | Missense Mutation (SNP) | VAF 281/588 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLAG1 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 45/694 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.137); called by muse, mutect2
- RUFY1 | c.926dup p.N309Kfs*7 | Frame Shift Ins (INS) | VAF 167/341 reads (49%) | called by mutect2, varscan2
- C5orf22 | c.1110C>T p.I370= | Silent (SNP) | VAF 335/717 reads (47%) | catalogued as rs781528558; called by muse, mutect2, varscan2
- CLASRP | c.942C>A p.R314= | Silent (SNP) | VAF 222/504 reads (44%) | catalogued as COSV99673914; called by mutect2, varscan2
- ITGA11 | c.2682C>T p.N894= | Silent (SNP) | VAF 221/465 reads (48%) | catalogued as rs368402640; called by muse, mutect2, varscan2
- MUC16 | c.11874A>T p.T3958= | Silent (SNP) | VAF 188/418 reads (45%) | called by muse, mutect2
- PRSS16 | c.6C>G p.A2= | Silent (SNP) | VAF 141/340 reads (41%) | called by muse, mutect2, varscan2
- DMXL2 | c.8333-56A>G | Intron (SNP) | VAF 186/397 reads (47%) | called by muse, mutect2, varscan2
- PPP6R2 | c.2601-635G>A | Intron (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- SCRN2 | c.175-45G>A | Intron (SNP) | VAF 136/460 reads (30%) | called by muse, varscan2
